Gene-level copy-number profile of tumor specimen ALCH-B2A4-TTR1-A from ALCHEMIST case ALCH-B2A4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 73.2 years (26,750 days).
Specimen ALCH-B2A4-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd0e4523-8395-4b65-85b5-148678275ea1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2A4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/20e23a05-2bd5-47d4-a844-5e99f6d0213e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 19; copy number 2: 13,059; copy number 3: 8,728; copy number 4: 31,900; copy number 5: 997; copy number 6: 3,958; copy number 7: 181; copy number 8: 5; copy number 11: 1; copy number 12: 6; copy number 14: 8.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:586,071–827,796, 1 gene (within-gene range 0–2): AL669831.3.
- chr1:629,062–810,065, 16 genes (within-gene range 0–2): MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3, AL669831.1, RNU6-1199P, AL669831.2, LINC01409, AL669831.6.
- chr1:27,234,632–27,308,636, 2 genes: WDTC1, Y_RNA.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–2): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr8:12,412,827–12,436,343, 4 genes: AC087203.3, FAM90A25P, ALG1L12P, FAM86B2.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–4): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,085,628–144,373,659, 8 genes, copy number 14: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr1:196,774,813–196,795,407, 1 gene, copy number 11: CFHR3.
- chr1:248,573,801–248,645,278, 6 genes, copy number 12: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
